Somatic mutation profile of tumor specimen 0DQS05 from CCDI case PBCFHT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Small cell sarcoma; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 14.4 years (5,253 days).
Specimen 0DQS05: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19412a4c-16d2-4325-8415-9482ed8c8aaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQS0M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf68f721-e528-406e-a4ab-698f943eccc7

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 3, Silent 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD26 | c.5000-1G>A p.X1667_splice | Splice Site (SNP) | VAF 24/856 reads (3%) | catalogued as rs1384975465; called by muse, mutect2
- CAMSAP3 | c.3586G>A p.A1196T | Missense Mutation (SNP) | VAF 157/355 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.071); catalogued as rs1393887283, COSV50331606; called by muse, mutect2, varscan2
- COA1 | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 339/839 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.104); catalogued as rs773883424; called by muse, mutect2, varscan2
- CSF3R | c.1711A>C p.N571H | Missense Mutation (SNP) | VAF 48/1010 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV100118431; called by muse, mutect2
- GLIS3 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 104/218 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs775044065, COSV60930310; called by muse, mutect2
- MAST2 | c.2549A>G p.N850S | Missense Mutation (SNP) | VAF 309/760 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1367424403; called by muse, mutect2, varscan2
- NPAP1 | c.1963C>A p.Q655K | Missense Mutation (SNP) | VAF 272/675 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as COSV61508680; called by muse, mutect2, varscan2
- PPP1R3A | c.2731C>G p.Q911E | Missense Mutation (SNP) | VAF 29/857 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99492974; called by muse, mutect2
- TANC1 | c.1013C>A p.T338K | Missense Mutation (SNP) | VAF 384/899 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV55093683; called by muse, mutect2, varscan2
- CELSR3 | c.6256_6272dup p.H2092Rfs*32 | Frame Shift Ins (INS) | VAF 120/386 reads (31%) | called by mutect2, varscan2
- FCRL3 | c.1823C>A p.A608D | Missense Mutation (SNP) | VAF 174/504 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by mutect2, varscan2
- KIF23 | c.2602G>T p.D868Y (on ENST00000260363; = p.D764Y on NM_004856.7) | Missense Mutation (SNP) | VAF 175/476 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MPHOSPH9 | c.2652A>G p.I884M | Missense Mutation (SNP) | VAF 32/1118 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, mutect2
- OXSR1 | c.71-1G>A p.X24_splice | Splice Site (SNP) | VAF 222/520 reads (43%) | called by muse, varscan2
- FCRL3 | c.1824C>T p.A608= | Silent (SNP) | VAF 194/573 reads (34%) | called by muse, mutect2, varscan2
- OPLAH | c.729C>G p.P243= | Silent (SNP) | VAF 52/820 reads (6%) | catalogued as COSV70678119; called by muse, mutect2
- BICD1 | c.2840+87C>T | Intron (SNP) | VAF 29/85 reads (34%) | catalogued as rs755485650, COSV55690164; called by muse, mutect2, varscan2
- CHD9 | c.1453-1237T>C | Intron (SNP) | VAF 180/441 reads (41%) | called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 6/52 reads (12%) | called by muse, varscan2
